MMRF case MMRF_1048 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ace7303c-286a-45f2-ac3f-f1a76810ebab

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.5 years (19,544 days); ISS stage: I; Days to last known disease status: 1,792 days (4.9 years); Days to last follow up: 1,792 days (4.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 81 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 81 days; Days to treatment end: 82 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 84 days; Days to treatment end: 84 days.
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 192 days; Days to treatment end: 953 days (2.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 2.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 729 mg/dL; Immunoglobulin G 2.62 g/L; Immunoglobulin A 29.9 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 1.82 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.53 mmol/L; Albumin 40 g/L; Total Protein 9.7 g/dL; Glucose 5.23 mmol/L.
- Day 29 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.28 mg/dL; Immunoglobulin G 2.7 g/L; Immunoglobulin A 3.05 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 1.2 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 282 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 5.78 mmol/L.
- Day 173: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 4.94 g/L; Immunoglobulin A 0.461 g/L; Immunoglobulin M 0.227 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 5.5 mmol/L.
- Day 259: Hemoglobin 8.37 mmol/L; Leukocytes 3 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 6.6 mmol/L.
- Day 362: Hemoglobin 7.87 mmol/L; Leukocytes 2.5 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.15 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 7.15 mmol/L.
- Day 446: Hemoglobin 7.87 mmol/L; Leukocytes 2.9 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 43 g/L; Total Protein 6.1 g/dL; Glucose 6.82 mmol/L.
- Day 557: Hemoglobin 8 mmol/L; Leukocytes 2.7 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 7.04 mmol/L.
- Day 642: Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L.
- Day 727: M Protein 0 g/dL; Hemoglobin 7.56 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.23 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 6.27 mmol/L.
- Day 931 (ECOG 2): Hemoglobin 8 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.99 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 5.56 mmol/L.
- Day 1,047: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Hemoglobin 8 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.07 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 7.59 mmol/L.
- Day 1,134 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Beta 2 Microglobulin 2.3 µg/mL; Hemoglobin 7.56 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.86 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 20 g/L; Total Protein 6.2 g/dL; Glucose 5.17 mmol/L.
- Day 1,225 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Hemoglobin 8.18 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 6.71 mmol/L.
- Day 1,412 (ECOG 1): Hemoglobin 8 mmol/L; Leukocytes 5.3 ×10⁹/L; Platelets 200 ×10⁹/L.
- Day 1,503: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.18 mg/dL; Hemoglobin 8.06 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.11 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 7.43 mmol/L.
- Day 1,617: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.45 mg/dL; Hemoglobin 8.56 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.99 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 5.5 mmol/L.
- Day 1,705: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.15 mg/dL; Hemoglobin 8.68 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.16 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 6.82 mmol/L.
- Day 1,792: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 37.8 mg/dL; Hemoglobin 8.12 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.42 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.67 mmol/L.

Other clinical attributes
- Day 1: Weight: 67 kg; Height: 161 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1048_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1048_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
